Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A22K, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A22K-01A (Primary Tumor).

[page 1 of 3]
ICD-0-3
path: Carcinoma, papillary and follicular 8340/3
CQCF: Carcinoma, papillary, thyroid, NOS 8260/3
Site: thyroid, NOS C73.9 4/22/11 hr

Surgical Pathology Consultation Report

Patient Name: _____
MRN: _____ Service: _____ Accession #: _____
DOB: _____ Visit #: _____ Collected: _____
Gender: F Location: _____ Received: _____
HCN: _____ Facility: _____ Reported: _____
Ordering MD: _____
Copy To: _____

Specimen(s) Received

1. Thyroid: total, stitch - left upper lobe, level 6 neck
2. Parathyroid: metastatic papillary CA ? Lt parathyroid QS
3. Neck: Contents Lt neck level 2-5

Diagnosis

1. Multifocal papillary carcinoma, dominant mixed classical and follicular variant with focal columnar cell change involving surgical margins, 1.1 cm, left ; mild nodular hyperplasia: Thyroid
No pathological diagnosis: Lymph node, isthmus
Metastatic papillary thyroid carcinoma: Lymph node, 1 of 2, left perithyroidal
Metastatic papillary thyroid carcinoma: Lymph nodes, 3 of 4, (level 6) neck
No pathological diagnosis: Parathyroid, left
- Total thyroidectomy specimen with (level 6) neck dissection specimen
2. Metastatic papillary thyroid carcinoma: Lymph node, (site listed as "left parathyroid") excisional biopsy
3. Metastatic papillary thyroid carcinoma: Lymph nodes, 5 of 75, (level 2-5 left) neck dissection specimen

Synoptic Data

Procedure: _____ Other: Total thyroidectomy with level 6 and level 2-5 left neck dissection
Received: _____ Fresh
Specimen Integrity: _____ Intact
Specimen Size: _____ Right lobe:
3.6 cm
1.8 cm
1.0 cm
Left lobe:
3.0 cm
1.0 cm
0.9 cm
Isthmus +/- pyramidal lobe:
2.5 cm
0.9 cm
0.6 cm
Central compartment:
3.5 cm

NIHAA Discrepancy		X
Dual/Syncronous Primary noted		X
Ref: _____	Date Reviewed: 4/22/11	hr

[page 2 of 3]
	1.5 cm
	0.6 cm
Specimen Weight:	12.8 g
Tumor Focality:	Multifocal, bilateral
----- DOMINANT TUMOR -----	
Tumor Laterality:	(Left lobe
Tumor Size:	Greatest dimension: 1.1 cm
	Additional dimension: 0.8 cm
	Additional dimension: 0.5 cm
Histologic Type:	Papillary carcinoma, classical (usual)
	Papillary carcinoma, columnar cell variant
	Papillary carcinoma, follicular variant
	Classical (papillary) architecture
	Follicular architecture
	Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margin(s) involved by carcinoma
Tumor Capsule:	Partially encapsulated
Tumor Capsular Invasion:	Present, extent minimal
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
----- SECOND TUMOR -----	
Tumor Laterality:	Right lobe
Tumor Size:	Greatest dimension: 0.9 cm
	Additional dimensions: 0.7 cm
Histologic Type:	Papillary carcinoma, follicular variant
	Papillary carcinoma, microcarcinoma (occult, small or microscopic) variant
	Follicular architecture
	Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	None
Tumor Capsular Invasion:	Not identified
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	m (multiple primary tumors)
Primary Tumor (pT):	pT1b: Tumor more than 1 cm but not more than 2 cm in greatest dimension, limited to the thyroid
Regional Lymph Nodes (pN):	pN1b: Metastases to unilateral, bilateral or contralateral cervical or superior mediastinal lymph nodes
	Number of regional lymph nodes examined: 83
	Number of regional lymph nodes involved: 10
	Lymph Node, Extranodal Extension Not identified
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Adenomatoid nodule(s) or Nodular follicular disease
	Parathyroid gland(s), within normal limits
	Other: additional multiple papillary microcarcinomas: right lobe: 0.6 cm, involving surgical margins, 0.1 cm and 0.1 cm; left lobe: 0.1 cm.

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified

by:

[page 3 of 3]
Gross Description

1. The specimen labeled with the patient's name and as "Thyroid: Total, stitch-left upper lobe, level 6 neck" consists of a thyroid gland with attached partial neck dissection that weighs 12.8 g. The right lobe measures 3.6 cm SI x 1.8 cm ML x 1.0 cm AP, the left lobe measures 3.0 cm SI x 1.0 cm ML x 0.9 cm AP and the isthmus measures 2.5 cm SI x 0.9 cm ML x 0.6 cm AP. The neck dissection measures 3.5 cm SI x 1.5 cm ML x 0.6 cm AP. No parathyroid glands are identified grossly. The external surface is painted with silver nitrate. The right lobe contains 2 delineated nodules that measure 0.6 cm in diameter and 0.7 cm SI x 0.9 cm ML x 0.6 cm AP. The left lobe contains one delineated nodule that measures 1.1 cm SI x 0.8 cm ML x 0.5 cm AP. Adherent to the lateral aspect of the left lobe is a second nodule that measures 2.2 cm SI x 1.0 cm ML x 0.5 cm AP. This nodule is partially calcified. The remainder of the thyroid tissue is pale red-brown. The neck dissection contains 4 lymph nodes that range in size from 0.3 to 1.5 cm. Sections of all 4 nodules and normal tissue are stored frozen. Representative sections of the remainder of the specimen are submitted as follows, thyroid in toto (except calcified portion of laterally adherent nodule):

1A-D right lobe, superior to inferior
1E-F isthmus
1G-J left lobe, superior to inferior
1K 3 lymph node
1L 1 lymph node, bisected

2. The specimen labeled with the patient's name and as "?metastatic papillary Ca ?Lt parathyroid" consists of 2 fragments of tissue that weigh 0.116 g and measure 0.5 x 0.4 x 0.3 cm and 0.5 x 0.5 x 0.4 cm. It is frozen for intraoperative consultation.

2A frozen section block resubmitted

3. The specimen labeled with the patient's name and as "Contents LT neck level 2-5", consists of an unoriented piece of fibrofatty tissue that measures 13 x 5 x 1.5 cm. Within the specimen are multiple probable lymph nodes that range in size from 0.2 to 3.2 cm. Several of the larger lymph nodes grossly appear to be involved by tumor. Representative sections:

3A-J multiple lymph nodes, per block
3J-M one lymph node bisected, per block
3N-P representative slice of each of the 3 largest lymph nodes, 1 per block

Quick Section Diagnosis

2. query metastatic papillary thyroid ca vs. left parathyroid, qs:

- Consistent with metastatic papillary thyroid carcinoma

OR called at

Source: NCI Genomic Data Commons file c605d6d5-c08e-4f00-a42d-e401248a5c70 (TCGA-EM-A22K.8AB1176E-9808-44F0-B0DB-B9D3D5027025.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).